Somatic mutation profile of tumor specimen 0DS0ZT from CCDI case PBCBTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.2 years (1,548 days).
Specimen 0DS0ZT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a83e4ff-4dea-4c16-8fc1-79e5c34ef042.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0Z7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3db6e261-8f60-455f-b314-3c6454d4b887

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QL4 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 170/712 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CD101 | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 215/643 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- KCNJ15 | c.1096A>G p.R366G | Missense Mutation (SNP) | VAF 24/857 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- TMEM30A | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 133/506 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MTHFD1 | c.2538A>G p.Q846= | Silent (SNP) | VAF 52/790 reads (7%) | catalogued as rs747245120; called by muse, mutect2
